Surgical pathology report (de-identified scan), TCGA case TCGA-68-8250, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-68-8250-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED]

SPECIMEN SUBMITTED:

Part A: RIGHT UPPER LOBE

Part B: 10R

Part C: 11R

Final Diagnosis

1. Right lung, upper lobe, lobectomy (A) - Moderately differentiated squamous cell carcinoma (see comment)
- Separate focus of minimally invasive adenocarcinoma (WHO adenocarcinoma, mixed type with bronchioloalveolar cell carcinoma and acinar components).
- Centrilobular emphysema.
2. Lymph nodes, 10R, 11R, excision (B, C) - Lymph nodes, negative for neoplasm.

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

1.

Tumor Location: Right upper lobe (squamous cell carcinoma and adenocarcinoma)

Tumor Size: Squamous cell carcinoma: 1.8 x 1.7 x 1.3 cm.

Adenocarcinoma: 1.5 x 1 x 0.8 cm. The focus of invasive acinar pattern measures 0.3 cm.

Vascular Invasion: not identified in any tumor.

Lymphatic Invasion: Present in the squamous cell carcinoma; not identified in the adenocarcinoma.

Bronchial Margin: Negative

Vascular Margin: Negative

Parenchymal Margins: Negative

Pleura/Soft Tissue Margin: Negative

Pathologic Stage (AJCC): The histopathologic morphology of the current squamous cell carcinoma is similar to the patient's previous squamous cell carcinoma in the left upper lobe which was reviewed for comparison, arguing in favor of a metastatic process. However, a second synchronous squamous cell carcinoma can not be excluded.

The pathologic staging for the adenocarcinoma is p stage IA (T1a N0 MX).

General comments: EGFR mutation analysis will be performed and the results reported as an addendum.

Procedure: EGFR Mutation Analysis Re

Status: Ordered

Text: {Not Entered}

Intraoperative Diagnosis:

A. Bronchial margin negative for carcinoma

Clinical Diagnosis:

LUNG NODULES

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received fresh at the frozen desk labeled "right upper lobe" is a lobectomy specimen of the upper lobe of the right lung (16 x 13 x 2.5 cm, 230 g). The pleura appears smooth with few anthracotic nodules and no retraction. A 1.8 x 1.7 x 1.3 cm firm tan-white poorly circumscribed nodule is present at 0.1 cm from the parenchymal surface and at 1 cm from the bronchial margin. The tumor does not invade through the pleura (inked blue). The remainder of the lung parenchyma appears red-brown. A slightly indurated subpleural area (1 cm) is present located 3 cm from the main nodule. Representative sections are submitted as follows: A1 bronchial margin shave frozen section, A2 bronchus, A3 vascular margin (vein), A4 parenchymal margin shave including artery, A5-A8 nodule, A9 peribronchial tissue with possible lymph nodes, A10 indurated lung parenchyma.

B. Received fresh labeled "10R" are multiple fragments of tan-pink soft tissue aggregating to 1.7 x 0.8 x 0.3 cm. Totally submitted in formalin in cassette B1.

C. Received fresh labeled "11R" is an irregular segment of tan-pink soft tissue measuring 1.0 x 0.8 x 0.4 cm. Totally submitted in formalin in cassette C1.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 48fe651c-7f3b-4266-94bc-d2b4313c80b4 (TCGA-68-8250.DB0359B7-58B4-456F-A905-C8DC2B3EA8A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).